Surgical pathology report (de-identified scan), TCGA case TCGA-06-5412, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5412-01A (Primary Tumor).

[page 1 of 3]
TCGA-06-5412

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] has experienced [REDACTED]. On imaging there is a large right temporoparietal mass with rim-enhancement and prominent associated vasogenic edema.

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, right parietal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right parietal, excisional biopsies:

A. Glioblastoma.

B. MIB-1 proliferation index: > 8%.

See Microscopy Description and Comment.

COMMENT

The neoplasm is a glioblastoma with brisk mitotic activity, a high MIB-1 proliferation index, focal microvascular cellular proliferation, and zones of tumor necrosis.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of

[page 2 of 3]
MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

PCR for EGFR variant III mutation
Date Ordered: [REDACTED] Date Reported: [REDACTED]
Interpretation
NEGATIVE - No evidence of EGFRvIII mutation is detected
Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

[page 3 of 3]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, right parietal tumor, excision biopsy: High histological grade glioma

(C/W glioblastoma). Touch preparation smears performed at

and results reported to the Physician of Record.

GROSS DESCRIPTION

A.

"Right parietal tumor," received fresh, three fragments, 0.7 cm in aggregate.

Soft, glistening, greyish-red. In total, A1 and A2.

can,

MICROSCOPIC DESCRIPTION

The sections contain an astrocytic (strong GFAP fibrillogenesis) neoplastic proliferation with nuclear anaplasia, brisk mitotic activity, focal microvascular cellular proliferation (better observed in the Tumor Tissue Bank

sections, vial 3 top), and zones of tumor necrosis. The CD34 depicts

the rich vascularity of the tumor. The CD163 demonstrates a heavy infiltration of the tumor by phagocytic cells. There are sparse lymphocytes highlighted by the LCA. With the MIB-1 there is an absolute proliferation index of about 8%, which in reality is probably at least three times greater when taking into account the large number of phagocytic cell nuclei within the

tumor mass.

ICD-9(s):

237.5 237.5

Histo Data

Part A: Brain, right parietal tumor, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
TPS H/E x 1	1		
CD163 Vector x 1	2		
CD34-DA x 1	2		
LCA-DA x 1	2		
EGFR vIII-curls x 1	2		
mGFAP-DA x 1	2		
H/E x 1	2		
MGMT-curls x 1	2		
MIB1-DA x 1	2		

*** End of Report ***

Source: NCI Genomic Data Commons file 7b90c0dc-a274-4cab-a220-8955cb8af027 (TCGA-06-5412.C88B9AB2-265C-4BB4-838F-98E88100EBBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).